Surgical pathology report (de-identified scan), TCGA case TCGA-19-4065, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-4065-02A (Recurrent Tumor).

SURGICAL PATHOLOGY REPORT

Name:
Accession #:
Date of Procedure:
Date Received:
Submitting Physician:

Med. Rec #.
Location:
Race:
DOB/Sex: (Age:) / M

FINAL DIAGNOSIS

A, B. RIGHT FRONTAL LOBE OF BRAIN, RECURRENT TUMOR, REMOVAL:
-- GLIOBLASTOMA WITH PROMINENT SPINDLE CELL DIFFERENTIATION (GLIOSARCOMA), SEE NOTE.

Note: Dural invasion is identified. The majority of the specimen consists of highly cellular viable appearing tumor.

Electronically Signed Out By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

A: Touch imprint and Microscopic: Malignant glioma invading dura.

Clinical History:

Recurrent GBM

Specimens Submitted As:

DURAL LEAFLET RULE OUT TUMOR INFILTRATION
B:R FRONTAL TUMOR

1CB-0-3

Glioblastoma, nos 9440/3

COCF Site: C71.9

Path Site: brain, frontal lobe C71.1

1/26/15

Gross Description:

A: Received fresh for intraoperative consultation, labeled with patient's name, hospital number, and "dural leaflet rule out tumor infiltration" are multiple pink-tan soft tissue fragments, 1.5 x 0.8 x 2.3 cm in aggregate. A touch imprint is performed. A portion is sent for frozen section. The remainder of the specimen is submitted entirely for permanent.

B: Received in formalin labeled with patient's name and number are two soft, tan-yellow and focally brown irregular tissue fragments measuring 2.0 x 0.6 x 0.4 cm and 2.0 x 1.0 x 1.0 cm. A portion of each fragment is submitted to [redacted]. Remaining tissue is entirely submitted in one cassette.

Source: NCI Genomic Data Commons file 7f926468-f0e5-4642-8f50-101c07976619 (TCGA-19-4065.E375DF88-891E-4DE4-89A9-B394429C445A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).